CPTAC case SC-0482 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/18a3f744-64f5-4c0a-8100-5cdec81c4f9c

Demographics
Sex at birth: male; Vital status: Dead; Days to death: 639 days (1.7 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin of trunk; Age at diagnosis: 40.0 years (14,610 days); AJCC staging edition: 8th; AJCC pathologic T: T4b; AJCC pathologic N: N3c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIID; Last known disease status: With tumor; Days to last known disease status: 639 days (1.7 years); Progression or recurrence: yes; Days to recurrence: 152 days; Clark level: IV.
   Pathology details: Breslow thickness: 10.

Biospecimens (1 sample)
- Sample S-1910-008133: Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Frozen; Initial weight: 109 mg; Method of sample procurement: Tumor Resection.
